Somatic mutation profile of tumor specimen MMRF_1450_1_BM_CD138pos (aliquot MMRF_1450_1_BM_CD138pos_T1_KAS5U_L01600) from MMRF case MMRF_1450, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,463 days).
Specimen MMRF_1450_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fd1fc10-719b-4be1-8c38-3d19126a07ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1450_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1450_1_PB_Whole_C2_KAS5U_L01609; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d07fa0fa-3751-4200-b57e-ed0efe53b75f

The open-access MAF lists 184 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 46, Intron 22, Silent 20, 5'UTR 7, 3'Flank 5, RNA 4, Frame Shift Del 3, Splice Region 3, Nonsense Mutation 3, Splice Site 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARVCF | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs865811145; called by muse, mutect2, varscan2
- BAHCC1 | c.4466G>C p.R1489P | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100311654; called by muse, mutect2, varscan2
- CAPRIN2 | c.1375A>C p.K459Q | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs751081932; called by muse, mutect2, varscan2
- CCDC77 | c.790A>C p.N264H | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV53471947; called by muse, mutect2, varscan2
- DMRTA1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1245784959; called by muse, mutect2, varscan2
- EMC1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753052916, COSV100617530; called by muse, mutect2, varscan2
- ERICH3 | c.2675C>A p.A892D | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV58614157; called by muse, mutect2, varscan2
- FAT3 | c.12809C>T p.S4270L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV99969672; called by muse, mutect2, varscan2
- FGF20 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201317229; called by muse, mutect2, varscan2
- FREM3 | c.3323C>G p.T1108R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100318535; called by muse, mutect2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- IGHV2-70 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375530938; called by muse, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- IGHV2-70 | c.147C>G p.S49R | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376260160; called by muse, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, varscan2
- IGLV3-1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs61731683; called by muse, varscan2
- IGLV3-1 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs559078152; called by muse, varscan2
- IGLV3-1 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs376677833; called by muse, varscan2
- IGLV3-1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs574479963; called by muse, varscan2
- IQCN | c.3028C>T p.R1010W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs768504480; called by muse, mutect2, varscan2
- IRS1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.825); catalogued as rs1289819083, COSV59335187; called by muse, mutect2, varscan2
- MTPAP | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 56/450 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.073); catalogued as COSV99554308; called by muse, mutect2, varscan2
- NEU4 | c.538C>T p.R180C (on ENST00000391969 / NM_001167602.3; = p.R192C on NM_080741.4) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs746318437; called by muse, mutect2, varscan2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2
- PHLDB1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 169/281 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs191697288, COSV61876790; called by muse, mutect2, varscan2
- RAD21L1 | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs563437729; called by muse, mutect2, varscan2
- RTP2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs765572958; called by muse, mutect2, varscan2
- SALL3 | c.1973C>T p.T658M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1456247442, COSV73306057; called by muse, mutect2
- SH3KBP1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65643856; called by muse, mutect2, varscan2
- SMOX | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1199337500, COSV53867229; called by muse, mutect2
- SPAG17 | c.3807T>A p.Y1269* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV60452690; called by muse, mutect2, varscan2
- SPATA31E1 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs200867582; called by muse, mutect2, varscan2
- TRIM2 | c.218G>A p.G73E (on ENST00000437508; = p.G100E on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58634254; called by muse, mutect2, varscan2
- ZSCAN5A | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV99569840; called by muse, mutect2, varscan2
- AFAP1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.2376G>C p.M792I | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.3509G>T p.R1170I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ASAP2 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ATRNL1 | c.1500T>A p.D500E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2
- CAD | c.5497-1G>C p.X1833_splice | Splice Site (SNP) | VAF 62/402 reads (15%) | called by muse, mutect2, varscan2
- CDV3 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CFAP74 | c.277del p.L93Ffs*6 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- CLK2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 63/77 reads (82%) | called by muse, mutect2, varscan2
- COL1A2 | c.3474C>A p.N1158K | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A3 | c.5919A>G p.G1973= | Splice Region (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- DIP2C | c.1510del p.D504Mfs*7 | Frame Shift Del (DEL) | VAF 28/38 reads (74%) | called by mutect2, pindel, varscan2
- DLX4 | c.480+6G>T | Splice Region (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- DYRK3 | c.1387G>T p.V463L | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- FAM171A2 | c.347-1G>A p.X116_splice | Splice Site (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- FAM47A | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FCGR2C | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2
- FSIP2 | c.6253G>T p.V2085L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- HMGXB3 | c.2825T>C p.V942A (on ENST00000613459; = p.V696A on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, mutect2
- KCNA4 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNC1 | c.1333T>A p.L445I | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCTD16 | c.163T>A p.F55I | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM5A | c.2843T>G p.L948R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- KIAA1522 | c.2603C>A p.S868Y (on ENST00000373480 / NM_001198972.2; = p.S927Y on NM_020888.3) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- LCK | c.377+8G>A | Splice Region (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- MBOAT4 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MICU2 | c.1196T>C p.L399S | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NR2F2 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PEG3 | c.3334T>A p.C1112S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLQ | c.4787C>T p.P1596L | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- PRKDC | c.5825G>A p.C1942Y | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRT | c.2454A>C p.E818D | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCN5A | c.5356C>G p.L1786V (on ENST00000333535 / NM_198056.3; = p.L1785V on NM_000335.5) | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC24A5 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 40/804 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A12 | c.1309-2A>G p.X437_splice | Splice Site (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- SLC6A1 | c.336dup p.L113Afs*94 | Frame Shift Ins (INS) | VAF 30/68 reads (44%) | called by mutect2, pindel, varscan2
- SPEF2 | c.1827G>T p.E609D | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SSB | c.602T>G p.V201G | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- TGDS | c.999_1000del p.N334Ffs*54 | Frame Shift Del (DEL) | VAF 82/131 reads (63%) | called by pindel, varscan2
- UACA | c.957A>G p.I319M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UBE2O | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF385B | c.585A>T p.K195N | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRB3 | c.798C>T p.C266= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs994820991, COSV100800038; called by muse, mutect2, varscan2
- ATF7IP | c.1761C>T p.A587= | Silent (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- C1QTNF4 | c.876C>T p.D292= | Silent (SNP) | VAF 68/148 reads (46%) | catalogued as rs775566188, COSV56783128; called by muse, mutect2, varscan2
- CCNH | c.444A>G p.L148= | Silent (SNP) | VAF 49/201 reads (24%) | called by muse, mutect2, varscan2
- EDIL3 | c.1050T>G p.T350= | Silent (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- FBXL6 | c.276G>A p.A92= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.342C>T p.Y114= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs772022074; called by muse, mutect2, varscan2
- MBD3L1 | c.444G>T p.L148= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as COSV59776779; called by muse, mutect2
- MCM3 | c.588A>G p.T196= (on ENST00000229854 / NM_001366374.2; = p.T186= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- NDN | c.306G>A p.A102= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs757964674, COSV100086557; called by muse, mutect2, varscan2
- PAK1IP1 | c.600C>A p.T200= | Silent (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- PIK3CD | c.1959C>T p.S653= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs536302735, COSV100740378; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIWIL1 | c.777T>C p.Y259= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs1472277520; called by muse, mutect2, varscan2
- PRPF38B | c.918T>G p.R306= | Silent (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.1005G>A p.K335= | Silent (SNP) | VAF 89/186 reads (48%) | catalogued as rs540126898, COSV100837858; called by muse, mutect2, varscan2
- SLC17A8 | c.1287C>T p.F429= | Silent (SNP) | VAF 89/196 reads (45%) | catalogued as rs771231356; called by muse, mutect2, varscan2
- SUMF1 | c.1108C>T p.L370= | Silent (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.70203T>A p.I23401= (on ENST00000591111; = p.I15977= on NM_003319.4) | Silent (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- ZNF329 | c.915C>T p.H305= | Silent (SNP) | VAF 54/205 reads (26%) | called by muse, mutect2, varscan2
- ZNF480 | c.675T>C p.H225= | Silent (SNP) | VAF 191/592 reads (32%) | catalogued as rs1195924278; called by muse, mutect2, varscan2
- AADACL3 | c.*2493T>C | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- AADACL3 | c.*2494C>A | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ABCA1 | c.*3307A>G | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- AC020637.1 | n.801-418A>T | Intron (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- AC020907.6 | c.-442C>T | 5'UTR (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- ACP3 | c.*491T>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- ADD2 | c.*907C>G | 3'UTR (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- ADM2 | c.*3102G>T | 3'UTR (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- AR | c.*3935G>T | 3'UTR (SNP) | VAF 33/38 reads (87%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 41/89 reads (46%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BCL7A | chr12:122021576 T>C | 5'Flank (SNP) | VAF 16/56 reads (29%) | catalogued as rs967273111; called by muse, mutect2, varscan2
- BMPR1B | chr4:95156392 G>C | 3'Flank (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- BRF1 | c.471+325dup | Intron (INS) | VAF 107/218 reads (49%) | catalogued as rs1271831504; called by mutect2, varscan2
- C14orf132 | chr14:96090705 G>A | 3'Flank (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
- C1orf141 | c.*501T>A | 3'UTR (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113454068 T>C | 3'Flank (SNP) | VAF 22/41 reads (54%) | called by mutect2, varscan2
- CHRDL1 | c.*841A>T | 3'UTR (SNP) | VAF 11/41 reads (27%) | catalogued as rs983486055; called by muse, mutect2, varscan2
- CHRDL1 | c.*840T>C | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- CNOT6 | c.*622T>C | 3'UTR (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- COL12A1 | c.9181+202T>G | Intron (SNP) | VAF 63/146 reads (43%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.319C>A | RNA (SNP) | VAF 70/155 reads (45%) | called by muse, mutect2, varscan2
- EIF4G2 | c.-70G>C | 5'UTR (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- EMC1 | c.*1308A>G | 3'UTR (SNP) | VAF 64/117 reads (55%) | called by muse, mutect2, varscan2
- EXOC6B | c.*2083A>C | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- EYA4 | chr6:133531186 T>C | 3'Flank (SNP) | VAF 37/95 reads (39%) | catalogued as rs1261122884; called by muse, mutect2, varscan2
- F11 | c.485+378A>G | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- FBXL3 | c.*1209C>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- GFUS | c.598+32C>T | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- GPBP1 | c.*193G>T | 3'UTR (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- GPD2 | c.*185A>G | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*1388A>G | 3'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- IFT46 | c.673-1249A>G | Intron (SNP) | VAF 31/280 reads (11%) | called by muse, mutect2, varscan2
- ITGA8 | c.*1838G>T | 3'UTR (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- IYD | c.*7207C>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- KCNC1 | c.*1598C>T | 3'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2
- KCNJ15 | c.*1168C>T | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- KCNMB3 | c.-482T>A | 5'UTR (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- KRTCAP3 | c.213+24C>T | Intron (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- LIMD1 | c.*1692C>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- LRRC74B | c.416-57A>T | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- MAP1LC3B | chr16:87392088 G>C | 5'Flank (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- MASP1 | c.1091-3267T>A | Intron (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*5026C>G | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- MFF | c.39-9C>T | Intron (SNP) | VAF 36/84 reads (43%) | catalogued as rs1241248651; called by muse, varscan2
- MPRIP | c.2164-3874G>A | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- NAP1L1 | c.430-1654T>C | Intron (SNP) | VAF 9/237 reads (4%) | called by muse, mutect2
- NEK10 | c.2091-13272C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs372635664; called by muse, mutect2, varscan2
- PABPC1 | c.-390A>C | 5'UTR (SNP) | VAF 30/66 reads (45%) | catalogued as rs113011740; called by muse, mutect2, varscan2
- PAMR1 | c.*56C>T | 3'UTR (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- PLAG1 | c.*1210G>T | 3'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- PLCL2 | c.3205-8541_3205-8539del | Intron (DEL) | VAF 47/109 reads (43%) | called by mutect2, pindel, varscan2
- PPARD | c.*1291G>T | 3'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- PPP2R2D | c.*3507C>T | 3'UTR (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*3370A>T | 3'UTR (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- PRKD1 | c.*379G>A | 3'UTR (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- PRTG | c.*7557T>C | 3'UTR (SNP) | VAF 75/210 reads (36%) | called by muse, mutect2, varscan2
- PTENP1 | n.1106G>A | RNA (SNP) | VAF 115/371 reads (31%) | catalogued as rs1294115678; called by muse, mutect2, varscan2
- RANBP3 | c.407-131G>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- RDH11 | chr14:67674713 G>A | 3'Flank (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- RFX7 | c.*1071dup | 3'UTR (INS) | VAF 75/161 reads (47%) | called by mutect2, pindel, varscan2
- RGS5 | c.-46G>C | 5'UTR (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- RMND5B | c.*2300C>T | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- RPLP0P2 | n.1425G>A | RNA (SNP) | VAF 32/68 reads (47%) | catalogued as rs770243344; called by muse, mutect2, varscan2
- RPS18 | c.292-18C>T | Intron (SNP) | VAF 23/53 reads (43%) | catalogued as rs755538206; called by muse, mutect2, varscan2
- RYR2 | c.14656-36T>C | Intron (SNP) | VAF 79/107 reads (74%) | called by muse, mutect2, varscan2
- SH3GL3 | c.45+43309C>T | Intron (SNP) | VAF 24/452 reads (5%) | called by muse, mutect2
- SHISA9 | c.563+5943T>C | Intron (SNP) | VAF 11/214 reads (5%) | catalogued as rs1389627433; called by muse, mutect2
- SLC1A5 | c.-53C>A | 5'UTR (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- SLC28A3 | c.*1774T>C | 3'UTR (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- SMIM15 | c.*747A>C | 3'UTR (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- SNTN | c.*2794G>A | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs148142917; called by muse, mutect2, varscan2
- SRCIN1 | c.2829+140A>G | Intron (SNP) | VAF 23/225 reads (10%) | called by muse, mutect2
- SSPN | c.*1671G>C | 3'UTR (SNP) | VAF 27/61 reads (44%) | catalogued as COSV54382072; called by muse, mutect2, varscan2
- STX11 | c.*565T>G | 3'UTR (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- TBR1 | c.969+131G>C | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TEDDM1 | c.*584A>T | 3'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- TGFBI | c.*590A>C | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- TMEM184C | c.*9G>A | 3'UTR (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- TMEM222 | c.*369A>G | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- TMX4 | c.*4362A>G | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.1337C>T | RNA (SNP) | VAF 8/46 reads (17%) | catalogued as rs1239403544; called by muse, mutect2, varscan2
- VSTM5 | c.*457C>A | 3'UTR (SNP) | VAF 76/153 reads (50%) | catalogued as rs374703660; called by muse, mutect2, varscan2
- WDR1 | c.*279G>A | 3'UTR (SNP) | VAF 73/162 reads (45%) | catalogued as rs984219672; called by muse, mutect2, varscan2
- ZC3H13 | c.*2574C>G | 3'UTR (SNP) | VAF 48/51 reads (94%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.994-15T>C | Intron (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- ZNF311 | c.-209T>C | 5'UTR (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- ZNF804A | c.*255A>C | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
